Somatic mutation profile of tumor specimen ALCH-AEKC-TTP1-A (aliquot ALCH-AEKC-TTP1-A-1-0-D-A618-36) from ALCHEMIST case ALCH-AEKC, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 74.1 years (27,065 days).
Specimen ALCH-AEKC-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5ecc5029-65ef-4995-9448-f3a2db8b9ed6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEKC-NB1-A (Blood Derived Normal), aliquot ALCH-AEKC-NB1-A-1-0-D-A618-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8ae33dd-c682-4148-99f8-e99a484609d2

The open-access MAF lists 206 somatic variants for this specimen: 144 protein-altering or splice-affecting, 37 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 116, Silent 37, Nonsense Mutation 16, Intron 10, 5'UTR 5, RNA 5, Splice Site 4, 3'Flank 3, Frame Shift Ins 2, Splice Region 2, Frame Shift Del 2, Translation Start Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.973G>T p.G325* | Nonsense Mutation (SNP) | VAF 63/237 reads (27%) | catalogued as rs863224500, COSV52982163, COSV53644278; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAM33 | c.1133+4C>A | Splice Region (SNP) | VAF 61/291 reads (21%) | catalogued as COSV100597875; called by muse, mutect2, varscan2
- ATIC | c.1702G>A p.D568N | Missense Mutation (SNP) | VAF 55/467 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52695110; called by muse, mutect2, varscan2
- BRD3 | c.568G>A p.V190I | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.56); PolyPhen benign (0.027); catalogued as rs150801538; called by muse, mutect2, varscan2
- CCT2 | c.1180C>G p.L394V | Missense Mutation (SNP) | VAF 71/738 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1486291228; called by muse, mutect2
- CILP2 | c.2443G>T p.G815C | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758866374; called by muse, mutect2, varscan2
- COL4A4 | c.4835G>C p.G1612A | Missense Mutation (SNP) | VAF 85/388 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61630398; called by muse, mutect2, varscan2
- COL8A1 | c.1208C>A p.P403H | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.921); catalogued as rs1357315131; called by muse, mutect2, varscan2
- DKK1 | c.91G>T p.A31S | Missense Mutation (SNP) | VAF 131/567 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.258); catalogued as COSV64760456; called by muse, mutect2, varscan2
- DNAH6 | c.9446G>A p.R3149Q | Missense Mutation (SNP) | VAF 22/285 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as rs1204905402, COSV99406448; called by muse, mutect2
- DNAH8 | c.2662C>T p.H888Y | Missense Mutation (SNP) | VAF 40/217 reads (18%) | SIFT tolerated (0.85); PolyPhen benign (0.216); catalogued as rs752353072; called by muse, mutect2, varscan2
- DOCK10 | c.713G>T p.C238F | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99287348; called by muse, mutect2, varscan2
- F11 | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 49/251 reads (20%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as rs367856671; called by muse, mutect2, varscan2
- F9 | c.373G>A p.G125R | Missense Mutation (SNP) | VAF 90/242 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM960579; called by muse, mutect2, varscan2
- FGA | c.427C>A p.R143S | Missense Mutation (SNP) | VAF 48/382 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); catalogued as COSV57394426; called by mutect2, varscan2
- FHOD1 | c.289G>T p.G97C | Missense Mutation (SNP) | VAF 69/264 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as rs1276797977, COSV99264111; called by muse, mutect2, varscan2
- FMN2 | c.2524G>C p.E842Q | Missense Mutation (SNP) | VAF 92/507 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.119); catalogued as COSV60425632; called by muse, mutect2, varscan2
- FMNL1 | c.1603G>C p.E535Q | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.029); catalogued as rs1281404380; called by muse, mutect2, varscan2
- FMNL2 | c.3157G>C p.D1053H | Missense Mutation (SNP) | VAF 36/446 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV104386780; called by muse, mutect2
- GGNBP2 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 15/333 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1361210605; called by muse, mutect2
- GJA1 | c.433G>T p.V145L | Missense Mutation (SNP) | VAF 59/508 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV56997234; called by muse, mutect2, varscan2
- GJA8 | c.398G>A p.S133N | Missense Mutation (SNP) | VAF 52/440 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs781873537; called by muse, mutect2, varscan2
- GRID2 | c.1171G>T p.G391* | Nonsense Mutation (SNP) | VAF 64/391 reads (16%) | catalogued as COSV56212827; called by muse, mutect2, varscan2
- GRID2 | c.2291C>A p.T764N | Missense Mutation (SNP) | VAF 47/400 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs755393743; called by muse, mutect2, varscan2
- IGSF22 | c.1781C>A p.A594D | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60036365; called by muse, mutect2, varscan2
- LAMA3 | c.2147G>A p.R716Q | Missense Mutation (SNP) | VAF 177/594 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs762434186; called by muse, mutect2, varscan2
- MAGI1 | c.4295C>T p.A1432V | Missense Mutation (SNP) | VAF 22/316 reads (7%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs1474945715; called by muse, mutect2
- MED12L | c.4942G>A p.G1648R | Missense Mutation (SNP) | VAF 16/294 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99855321; called by muse, mutect2
- MYO5A | c.4712A>G p.Y1571C | Missense Mutation (SNP) | VAF 184/850 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100698212; called by muse, varscan2
- OLFM4 | c.204G>T p.Q68H | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV54579937; called by muse, mutect2, varscan2
- OR10A5 | c.124G>T p.G42* | Nonsense Mutation (SNP) | VAF 143/558 reads (26%) | catalogued as COSV55053812; called by muse, mutect2, varscan2
- OR10A5 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 143/558 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs867881604; called by muse, mutect2, varscan2
- OR5L2 | c.754C>A p.H252N | Missense Mutation (SNP) | VAF 55/257 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV65725095; called by muse, mutect2, varscan2
- OR5L2 | c.755A>T p.H252L | Missense Mutation (SNP) | VAF 55/254 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs761437303; called by muse, mutect2, varscan2
- PAPPA2 | c.4406C>G p.P1469R | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as COSV62796207, COSV62815949; called by muse, mutect2
- PIK3R2 | c.82G>A p.G28S | Missense Mutation (SNP) | VAF 55/214 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs112165780; called by muse, mutect2, varscan2
- PLCB1 | c.1460C>T p.S487F | Missense Mutation (SNP) | VAF 67/237 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as rs1376374003, COSV62039741; called by muse, mutect2, varscan2
- PNLIP | c.1015G>T p.G339C | Missense Mutation (SNP) | VAF 29/220 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as COSV65042424; called by muse, mutect2, varscan2
- POGLUT3 | c.679A>G p.R227G | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60212009; called by muse, varscan2
- POTEC | c.311A>G p.H104R | Missense Mutation (SNP) | VAF 197/1043 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.066); catalogued as rs1464089429; called by muse, mutect2, varscan2
- PRSS41 | c.482G>T p.R161L | Missense Mutation (SNP) | VAF 123/775 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as rs752512780, COSV68672148; called by muse, mutect2, varscan2
- PYHIN1 | c.1127G>A p.C376Y | Missense Mutation (SNP) | VAF 18/300 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.939); catalogued as COSV63721912; called by muse, mutect2
- REG1B | c.183+1G>A p.X61_splice | Splice Site (SNP) | VAF 114/427 reads (27%) | catalogued as rs774041730, COSV59306124; called by muse, mutect2, varscan2
- SPSB4 | c.740C>A p.S247* | Nonsense Mutation (SNP) | VAF 64/350 reads (18%) | catalogued as COSV60148727; called by muse, mutect2, varscan2
- TEFM | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 120/571 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as rs1192720689; called by muse, varscan2
- TRIM7 | c.1378C>T p.R460C | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51253509; called by muse, mutect2
- TTN | c.77897T>C p.V25966A (on ENST00000591111; = p.V18542A on NM_003319.4) | Missense Mutation (SNP) | VAF 124/497 reads (25%) | PolyPhen benign (0.169); catalogued as rs752494467, COSV60293819; called by muse, mutect2, varscan2
- UBQLNL | c.1156A>G p.I386V | Missense Mutation (SNP) | VAF 64/239 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1442285941; called by muse, mutect2, varscan2
- WNK2 | c.3289C>T p.P1097S | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs151176657; called by muse, mutect2, varscan2
- XIRP2 | c.2425G>A p.E809K (on ENST00000628543; = p.E984K on NM_152381.6) | Missense Mutation (SNP) | VAF 47/175 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753832931, COSV54688281; called by muse, mutect2, varscan2
- XYLT2 | c.2011G>A p.E671K | Missense Mutation (SNP) | VAF 53/180 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV50017875; called by muse, varscan2
- ZAN | c.5385G>T p.Q1795H | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as COSV61808085; called by muse, mutect2, varscan2
- ZDHHC5 | c.36C>A p.S12R | Missense Mutation (SNP) | VAF 16/298 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV54707786; called by muse, mutect2
- ABCB10 | c.1369A>C p.K457Q | Missense Mutation (SNP) | VAF 45/223 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- ABHD2 | c.409C>G p.H137D | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ADAMTS18 | c.2152G>T p.G718W | Missense Mutation (SNP) | VAF 129/406 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANO5 | c.1133T>A p.F378Y | Missense Mutation (SNP) | VAF 112/488 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGAP33 | c.1763G>T p.G588V | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ARID1A | c.5762C>A p.T1921N | Missense Mutation (SNP) | VAF 66/342 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- ATN1 | c.1519T>A p.S507T | Missense Mutation (SNP) | VAF 16/332 reads (5%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2
- BLMH | c.215G>C p.R72P | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C10orf82 | c.650del p.C217Sfs*7 | Frame Shift Del (DEL) | VAF 21/163 reads (13%) | called by mutect2, pindel, varscan2
- CCDC137 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 16/223 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.007); called by muse, mutect2
- CD1C | c.976C>A p.H326N | Missense Mutation (SNP) | VAF 30/302 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.265); called by muse, mutect2
- CD93 | c.1115G>T p.G372V | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEP135 | c.2608G>T p.A870S | Missense Mutation (SNP) | VAF 91/532 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- CNNM1 | c.875G>A p.G292E | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); called by mutect2, varscan2
- COL6A6 | c.1601G>A p.G534E | Missense Mutation (SNP) | VAF 59/258 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CRAMP1 | c.3573G>T p.L1191F | Missense Mutation (SNP) | VAF 56/290 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRYL1 | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 55/199 reads (28%) | called by muse, mutect2, varscan2
- CSMD2 | c.9448-1G>T p.X3150_splice | Splice Site (SNP) | VAF 28/150 reads (19%) | called by muse, mutect2, varscan2
- CTTNBP2 | c.656G>C p.R219T | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- DCHS1 | c.3277G>C p.V1093L | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DNAH3 | c.5938C>G p.R1980G | Missense Mutation (SNP) | VAF 34/328 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAJC1 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 68/246 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, varscan2
- DSP | c.3665A>G p.K1222R | Missense Mutation (SNP) | VAF 105/520 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- EPHB4 | c.2234A>G p.N745S | Missense Mutation (SNP) | VAF 73/262 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ESR1 | c.904A>C p.K302Q | Missense Mutation (SNP) | VAF 105/389 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- F13B | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 159/581 reads (27%) | called by muse, mutect2, varscan2
- FBLN5 | c.844G>T p.D282Y | Missense Mutation (SNP) | VAF 76/456 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FBXO15 | c.995+1G>T p.X332_splice | Splice Site (SNP) | VAF 18/227 reads (8%) | called by muse, mutect2
- FLNA | c.3226G>T p.G1076W | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- FLNC | c.5553G>T p.Q1851H | Missense Mutation (SNP) | VAF 205/542 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FN1 | c.2812C>A p.R938S | Missense Mutation (SNP) | VAF 49/387 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HEPH | c.571G>T p.A191S (on ENST00000343002; = p.A245S on NM_138737.5) | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); called by muse, varscan2
- ITGB3 | c.95C>T p.T32I | Missense Mutation (SNP) | VAF 155/583 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- JAKMIP1 | c.1079T>A p.L360H | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LILRB2 | c.392G>A p.S131N | Missense Mutation (SNP) | VAF 16/223 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); called by muse, mutect2
- LRP1B | c.8137G>C p.E2713Q | Missense Mutation (SNP) | VAF 52/546 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MED14 | c.3259C>A p.P1087T | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.987); called by muse, mutect2
- MLYCD | c.319G>C p.A107P | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- MMD2 | c.382C>A p.L128M | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MMP9 | c.1544C>A p.A515D | Missense Mutation (SNP) | VAF 106/341 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- MORC2 | c.905C>G p.A302G (on ENST00000397641 / NM_001303256.3; = p.A240G on NM_014941.3) | Missense Mutation (SNP) | VAF 102/232 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MTF1 | c.1285G>T p.E429* | Nonsense Mutation (SNP) | VAF 98/425 reads (23%) | called by muse, mutect2, varscan2
- MTUS2 | c.816G>C p.E272D | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- MUC16 | c.4762G>T p.E1588* | Nonsense Mutation (SNP) | VAF 53/170 reads (31%) | called by muse, mutect2, varscan2
- N4BP2L1 | c.19C>T p.Q7* | Nonsense Mutation (SNP) | VAF 16/34 reads (47%) | called by muse, varscan2
- NBEA | c.1306G>A p.D436N | Missense Mutation (SNP) | VAF 60/170 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- NOVA1 | c.937G>T p.V313L | Missense Mutation (SNP) | VAF 50/299 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, varscan2
- OR2A42 | c.316T>A p.F106I | Missense Mutation (SNP) | VAF 193/968 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- OR2W1 | c.628C>A p.P210T | Missense Mutation (SNP) | VAF 41/186 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- P2RY8 | c.525C>A p.C175* | Nonsense Mutation (SNP) | VAF 41/126 reads (33%) | called by muse, mutect2, varscan2
- PCDHGA9 | c.2266G>T p.E756* | Nonsense Mutation (SNP) | VAF 61/182 reads (34%) | called by muse, mutect2, varscan2
- PCGF6 | c.712A>G p.K238E | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PIM3 | c.253G>T p.A85S | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.78); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PLD1 | c.752C>T p.S251L | Missense Mutation (SNP) | VAF 70/563 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.392); called by muse, varscan2
- PLEKHG4B | c.3205G>T p.E1069* (on ENST00000283426; = p.E1425* on NM_052909.5) | Nonsense Mutation (SNP) | VAF 100/321 reads (31%) | called by muse, mutect2, varscan2
- PTGFR | c.631T>A p.L211I | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.912); called by muse, mutect2
- PUM1 | c.532G>T p.G178* | Nonsense Mutation (SNP) | VAF 39/229 reads (17%) | called by muse, mutect2, varscan2
- PURB | c.742A>T p.S248C | Missense Mutation (SNP) | VAF 125/421 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RFX6 | c.1310C>A p.S437Y | Missense Mutation (SNP) | VAF 29/497 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.031); called by muse, mutect2
- RMND5A | c.980dup p.C328Vfs*19 | Frame Shift Ins (INS) | VAF 26/110 reads (24%) | called by mutect2, pindel, varscan2
- RNF165 | c.-4_1del | Translation Start Site (DEL) | VAF 44/217 reads (20%) | called by pindel, varscan2
- RTL4 | c.864C>A p.H288Q | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RUFY4 | c.374C>T p.S125L | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- SATB1 | c.2132G>A p.G711D | Missense Mutation (SNP) | VAF 356/1165 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- SH3GL2 | c.235G>T p.G79C | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC35F1 | c.480C>A p.L160= | Splice Region (SNP) | VAF 25/97 reads (26%) | called by muse, mutect2
- SLC4A3 | c.180G>T p.E60D | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); called by muse, mutect2
- SLC9A9 | c.1755T>A p.D585E | Missense Mutation (SNP) | VAF 65/362 reads (18%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- SORCS1 | c.1150T>G p.S384A | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPEG | c.6781C>G p.P2261A | Missense Mutation (SNP) | VAF 117/425 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPOCK3 | c.940+1G>T p.X314_splice | Splice Site (SNP) | VAF 22/110 reads (20%) | called by muse, varscan2
- SPOCK3 | c.940G>T p.D314Y | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); called by muse, varscan2
- STEAP4 | c.826T>C p.Y276H | Missense Mutation (SNP) | VAF 58/242 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SUN3 | c.901G>T p.G301C | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SV2A | c.1237A>T p.T413S | Missense Mutation (SNP) | VAF 16/264 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.034); called by muse, mutect2
- TLL1 | c.2887G>T p.G963C | Missense Mutation (SNP) | VAF 54/296 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TOR3A | c.164_165insCG p.A57Vfs*46 | Frame Shift Ins (INS) | VAF 16/119 reads (13%) | called by mutect2, pindel, varscan2
- TRANK1 | c.760G>T p.G254* | Nonsense Mutation (SNP) | VAF 25/85 reads (29%) | called by muse, mutect2, varscan2
- TRAPPC11 | c.2326G>T p.V776F | Missense Mutation (SNP) | VAF 44/248 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- TRIM10 | c.27C>A p.S9R | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); called by muse, mutect2
- TRIP11 | c.4714G>C p.D1572H | Missense Mutation (SNP) | VAF 100/462 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- TRMT1L | c.2048A>C p.Q683P | Missense Mutation (SNP) | VAF 81/262 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- TSPYL2 | c.70G>C p.D24H | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.63); called by muse, varscan2
- TTN | c.44435C>A p.P14812H (on ENST00000591111; = p.P7388H on NM_003319.4) | Missense Mutation (SNP) | VAF 13/51 reads (25%) | PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- VN1R2 | c.624C>A p.Y208* | Nonsense Mutation (SNP) | VAF 163/369 reads (44%) | called by muse, mutect2, varscan2
- ZGPAT | c.542del p.P181Rfs*35 | Frame Shift Del (DEL) | VAF 145/662 reads (22%) | called by mutect2, pindel, varscan2
- ZNF260 | c.360G>T p.M120I | Missense Mutation (SNP) | VAF 183/726 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF273 | c.1654G>A p.D552N | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF37A | c.986G>T p.C329F | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ZNF653 | c.737T>A p.F246Y | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- ZNF804A | c.2803G>T p.E935* | Nonsense Mutation (SNP) | VAF 81/368 reads (22%) | called by muse, mutect2, varscan2
- AHCTF1 | c.4080G>A p.P1360= (on ENST00000366508; = p.P1334= on NM_015446.5) | Silent (SNP) | VAF 87/270 reads (32%) | catalogued as rs773982016, COSV58250280; called by muse, mutect2, varscan2
- AP002512.3 | c.774C>G p.V258= | Silent (SNP) | VAF 60/330 reads (18%) | called by muse, mutect2, varscan2
- BPIFB1 | c.210C>T p.I70= | Silent (SNP) | VAF 47/179 reads (26%) | called by muse, mutect2, varscan2
- C3orf33 | c.33G>C p.P11= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as rs996044580; called by muse, mutect2, varscan2
- CCDC80 | c.390G>A p.L130= | Silent (SNP) | VAF 115/445 reads (26%) | called by muse, mutect2, varscan2
- CD163 | c.645A>T p.G215= | Silent (SNP) | VAF 107/393 reads (27%) | catalogued as COSV100776007; called by muse, mutect2, varscan2
- CEP295NL | c.609A>G p.K203= | Silent (SNP) | VAF 54/117 reads (46%) | called by muse, mutect2, varscan2
- CRISP1 | c.105C>A p.T35= | Silent (SNP) | VAF 52/208 reads (25%) | catalogued as rs145871288; called by muse, mutect2, varscan2
- DLG5 | c.5349C>T p.V1783= | Silent (SNP) | VAF 42/345 reads (12%) | called by muse, mutect2, varscan2
- DNER | c.1374G>T p.P458= | Silent (SNP) | VAF 60/479 reads (13%) | called by muse, mutect2, varscan2
- FMNL1 | c.1602A>C p.A534= | Silent (SNP) | VAF 8/45 reads (18%) | called by muse, mutect2, varscan2
- GPT | c.972C>T p.G324= | Silent (SNP) | VAF 26/204 reads (13%) | catalogued as rs1368184040; called by muse, mutect2, varscan2
- KCNH2 | c.2793G>T p.P931= | Silent (SNP) | VAF 34/89 reads (38%) | called by muse, mutect2, varscan2
- KCNN1 | c.111G>T p.P37= | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as rs1225676157; called by muse, mutect2, varscan2
- LHCGR | c.846T>C p.F282= | Silent (SNP) | VAF 88/598 reads (15%) | called by muse, mutect2, varscan2
- MDGA1 | c.225G>C p.T75= | Silent (SNP) | VAF 27/95 reads (28%) | called by muse, mutect2, varscan2
- MDGA2 | c.1614C>A p.G538= (on ENST00000399232 / NM_001113498.2; = p.G240= on NM_182830.4) | Silent (SNP) | VAF 54/353 reads (15%) | called by muse, mutect2, varscan2
- MYH7 | c.5193T>C p.D1731= | Silent (SNP) | VAF 97/753 reads (13%) | called by muse, mutect2, varscan2
- OR8J3 | c.9T>C p.P3= | Silent (SNP) | VAF 28/122 reads (23%) | called by muse, mutect2
- PDZRN3 | c.2388G>T p.G796= | Silent (SNP) | VAF 73/314 reads (23%) | called by muse, mutect2, varscan2
- PHC3 | c.651A>G p.T217= (on ENST00000494943 / NM_001308116.2; = p.T229= on NM_024947.4) | Silent (SNP) | VAF 98/404 reads (24%) | catalogued as rs1444348269; called by muse, mutect2, varscan2
- PODXL | c.48G>T p.T16= | Silent (SNP) | VAF 14/56 reads (25%) | called by muse, mutect2, varscan2
- PTCHD4 | c.1299G>A p.T433= | Silent (SNP) | VAF 69/302 reads (23%) | catalogued as rs771084561, COSV59781838; called by muse, mutect2, varscan2
- RGS3 | c.207C>T p.Y69= | Silent (SNP) | VAF 27/89 reads (30%) | called by muse, mutect2, varscan2
- RGSL1 | c.1260G>A p.G420= | Silent (SNP) | VAF 140/353 reads (40%) | called by muse, mutect2, varscan2
- SALL3 | c.141C>A p.G47= | Silent (SNP) | VAF 12/130 reads (9%) | catalogued as COSV73305894; called by muse, mutect2
- SFMBT2 | c.699G>A p.L233= | Silent (SNP) | VAF 64/409 reads (16%) | called by muse, mutect2, varscan2
- SLC22A24 | c.876A>G p.L292= | Silent (SNP) | VAF 45/243 reads (19%) | called by muse, mutect2, varscan2
- SLC2A4 | c.1116C>T p.L372= | Silent (SNP) | VAF 105/346 reads (30%) | called by muse, mutect2, varscan2
- SMC5 | c.1164G>A p.K388= | Silent (SNP) | VAF 143/517 reads (28%) | called by muse, mutect2, varscan2
- TAS2R9 | c.87A>T p.L29= | Silent (SNP) | VAF 80/287 reads (28%) | called by muse, mutect2, varscan2
- TKFC | c.420C>T p.D140= | Silent (SNP) | VAF 32/169 reads (19%) | catalogued as rs1476668765; called by muse, mutect2, varscan2
- TMIGD3 | c.348C>T p.N116= (on ENST00000369717 / NM_001081976.2; = p.N197= on NM_020683.7) | Silent (SNP) | VAF 24/208 reads (12%) | called by muse, varscan2
- VIPR2 | c.513G>C p.L171= | Silent (SNP) | VAF 24/247 reads (10%) | called by muse, mutect2
- VPS8 | c.816A>T p.T272= (on ENST00000625842 / NM_001349294.1; = p.T270= on NM_015303.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 53/424 reads (13%) | called by muse, varscan2
- ZIC1 | c.60C>T p.S20= | Silent (SNP) | VAF 32/136 reads (24%) | catalogued as rs778083869; called by muse, mutect2, varscan2
- ZNF681 | c.987G>A p.K329= | Silent (SNP) | VAF 48/250 reads (19%) | called by muse, mutect2, varscan2
- ADAM23 | c.-50G>T | 5'UTR (SNP) | VAF 6/23 reads (26%) | called by muse, mutect2, varscan2
- BMX | c.*1A>T | 3'UTR (SNP) | VAF 57/114 reads (50%) | called by muse, mutect2, varscan2
- EBNA1BP2 | chr1:43172382 G>C | 5'Flank (SNP) | VAF 42/254 reads (17%) | catalogued as rs1365625220; called by muse, mutect2, varscan2
- ELK4 | c.-97G>C | 5'UTR (SNP) | VAF 47/255 reads (18%) | called by muse, mutect2, varscan2
- EPG5 | c.-13C>T | 5'UTR (SNP) | VAF 15/82 reads (18%) | catalogued as rs755470510; called by muse, mutect2, varscan2
- FAM120C | c.699+8367_699+8369del | Intron (DEL) | VAF 40/103 reads (39%) | called by pindel, varscan2
- GLIPR1L1 | chr12:75371462 C>G | 3'Flank (SNP) | VAF 18/80 reads (23%) | called by muse, mutect2, varscan2
- GLIPR1L1 | chr12:75371463 C>A | 3'Flank (SNP) | VAF 18/81 reads (22%) | called by muse, mutect2, varscan2
- GUCY2EP | n.940G>T | RNA (SNP) | VAF 25/191 reads (13%) | called by muse, mutect2, varscan2
- ITGA2B | c.2841+45G>T | Intron (SNP) | VAF 20/100 reads (20%) | called by muse, mutect2, varscan2
- KRT18 | c.417+26C>T | Intron (SNP) | VAF 222/867 reads (26%) | called by muse, mutect2, varscan2
- LIN7C | c.-15A>T | 5'UTR (SNP) | VAF 79/277 reads (29%) | called by muse, mutect2, varscan2
- MYO1F | c.2622-42_2622-41del | Intron (DEL) | VAF 12/45 reads (27%) | called by mutect2, pindel, varscan2
- NAA15 | chr4:139393624 G>A | 3'Flank (SNP) | VAF 26/224 reads (12%) | called by muse, varscan2
- NRXN1 | c.3365-109987G>T | Intron (SNP) | VAF 54/138 reads (39%) | called by muse, varscan2
- OR2L1P | n.524A>T | RNA (SNP) | VAF 59/568 reads (10%) | called by muse, mutect2, varscan2
- PLEKHF1 | c.-17+16G>A | Intron (SNP) | VAF 26/161 reads (16%) | called by muse, mutect2, varscan2
- REXO1L1P | n.24C>T | RNA (SNP) | VAF 101/1199 reads (8%) | catalogued as rs1261169280; called by muse, mutect2, varscan2
- RPS4XP21 | n.452C>T | RNA (SNP) | VAF 120/328 reads (37%) | called by muse, mutect2, varscan2
- SHANK2 | c.1174+32669T>A | Intron (SNP) | VAF 17/249 reads (7%) | called by muse, mutect2
- STMN3 | c.-40C>A | 5'UTR (SNP) | VAF 25/98 reads (26%) | called by muse, mutect2, varscan2
- TGM2 | c.1616-235G>A | Intron (SNP) | VAF 46/181 reads (25%) | called by muse, mutect2, varscan2
- TUBB7P | n.331G>T | RNA (SNP) | VAF 10/365 reads (3%) | called by muse, mutect2
- TXLNB | c.1077+97G>T | Intron (SNP) | VAF 11/239 reads (5%) | called by muse, mutect2
- UBE4A | c.721+17G>A | Intron (SNP) | VAF 33/234 reads (14%) | called by muse, mutect2, varscan2
